Surgical pathology report (de-identified scan), TCGA case TCGA-26-1799, project TCGA-GBM (Glioblastoma Multiforme), tissue source site University of Florida, specimen TCGA-26-1799-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation / Department of Pathology

SPECIMEN(S) SUBMITTED/ PROCEDURES ORDERED:

- A. Brain mass (88307) A. Frozen Section Charge (88331)
B. Brain mass (88307)

CLINICAL HISTORY:

[REDACTED] blood pressure in 200s. Brain mass at left temporal lobe.

GROSS DESCRIPTION: Received the following specimens in the Department of Pathology, labeled with the patient's name and hospital #:

- A. Brain mass
B. Brain mass
A. The specimen is received fresh, labeled "brain mass," and consists of a 1.0 x 0.8 x 0.6 cm portion of tan to beige soft tissue. A representative portion is submitted for frozen section. Frozen section diagnosis is, "Malignant glioma." By Dr. [REDACTED] The frozen section tissue is submitted entirely for permanent processing in cassette FSA1 and the remaining tissue is submitted in cassette A2. [REDACTED]
B. The specimen is received fresh, labeled "brain mass," and consists of a 4.5 x 4.0 x 1.6 cm irregular ovoid portion of cortical gray matter and underlying subcortical white matter. Sectioning reveals partially lodged gray and white interface. No discrete masses are seen. Representative portion of tissue is submitted for [REDACTED] Tumor Bank. The remaining tissue is submitted in cassettes B1-B7. [REDACTED]

DIAGNOSIS:

- A. Brain mass:
Glioblastoma multiforme (WHO Grade IV astrocytoma).
B. Brain mass:
Glioblastoma multiforme (WHO Grade IV astrocytoma).

"I, or my qualified designee, have performed the gross examination and description and I have personally reviewed the gross description and specimen preparations referenced herein, and have personally issued this report."

Resident/Prosector/Pathologist: [REDACTED]

ICD9 Codes: 191.9

[REDACTED]

[page 2 of 2]
Note: Test systems have been developed and their performance characteristics determined by [REDACTED] Medical Laboratories. Some tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance is not necessary. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] as qualified to perform high complexity clinical laboratory testing.

Pathologist

Electronically signed [REDACTED]

[REDACTED] TCGA-26-1799

Source: NCI Genomic Data Commons file 61d2049a-3449-46ae-94fd-54257bd1cdcc (TCGA-26-1799.946926E0-E570-4349-ACFF-922F546129FA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).